Somatic mutation profile of tumor specimen TCGA-AO-A1KP-01A (aliquot TCGA-AO-A1KP-01A-11D-A13L-09) from TCGA case TCGA-AO-A1KP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.3 years (28,247 days).
Specimen TCGA-AO-A1KP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5335ff43-f0e6-4870-ab47-635ba5b7256b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A1KP-10A (Blood Derived Normal), aliquot TCGA-AO-A1KP-10A-01W-A14R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/463fb9a0-b2a7-45f7-aca8-6e684e72fe43

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF3 | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1474730899, COSV100419751, COSV57860905; called by muse, mutect2, varscan2
- ASB5 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.325); catalogued as COSV56672241, COSV56672336; called by muse, mutect2, varscan2
- CACNA1F | c.1496T>A p.L499Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as COSV59905482; called by muse, mutect2, varscan2
- CMYA5 | c.8849G>T p.G2950V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71407371; called by muse, mutect2, varscan2
- DNAH17 | c.4916A>C p.E1639A | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67757947; called by muse, mutect2, varscan2
- DPY19L4 | c.1848+2T>A p.X616_splice | Splice Site (SNP) | VAF 62/178 reads (35%) | catalogued as COSV68963291; called by muse, mutect2, varscan2
- FRYL | c.6191T>G p.L2064R | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51952771; called by muse, mutect2, varscan2
- KIF1B | c.2761A>G p.T921A (on ENST00000377086 / NM_001365952.1; = p.T875A on NM_015074.3) | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.899); catalogued as COSV55811494; called by muse, mutect2, varscan2
- KRTAP23-1 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.537); catalogued as COSV61935742; called by muse, mutect2, varscan2
- RBBP5 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV52705570; called by muse, mutect2, varscan2
- SYNPO2L | c.2459T>C p.F820S (on ENST00000394810 / NM_001114133.3; = p.F596S on NM_024875.5) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV65738021; called by muse, mutect2, varscan2
- UHRF1BP1L | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV54439514; called by muse, mutect2, varscan2
- ZNF764 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV53222218; called by muse, mutect2
- CLSTN3 | c.1338G>A p.E446= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV56938179; called by muse, mutect2, varscan2
- FGF6 | c.321C>T p.S107= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs775761160, COSV57404079; called by muse, mutect2, varscan2
- LAMA1 | c.7749G>A p.A2583= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs761477714, COSV67539352; called by muse, mutect2, varscan2
- OTUD4 | c.2682G>A p.L894= (on ENST00000447906 / NM_001366057.1; = p.L829= on NM_001102653.1) | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs373270757, COSV71382042; called by muse, mutect2, varscan2
- PCDHA4 | c.1521C>T p.Y507= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1212194365, COSV63541674; called by muse, mutect2, varscan2
- DYRK3 | c.78-687A>G | Intron (SNP) | VAF 119/216 reads (55%) | catalogued as COSV65606860; called by muse, mutect2, varscan2
